Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8421, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8421-01A (Primary Tumor).

[page 1 of 2]
Report Status:

LEFT KIDNEY, RADICAL NEPHRECTOMY:

RENAL CELL CARCINOMA, (12.8 cm) Fuhrman nuclear grade 3 of 4, chromophobe type.

The tumor is confined to the renal parenchyma.

The renal vein, ureter, and inked soft tissue margins are free of tumor.

Lymphatic vascular invasion is not seen.

The renal parenchyma away from the tumor will be reported separately as an addendum.

Two lymph nodes are free of tumor.

AJCC (1997) stage T2 N0 MX.

NOTE: Hale's colloidal iron stain is positive supporting the diagnosis.

SURGICAL ADDENDUM:

LEFT NEPHRECTOMY

KIDNEY PARENCHYMA AWAY FROM THE TUMOR SHOWS NO SPECIFIC ABNORMALITIES

MICROSCOPIC DESCRIPTION:

Representative sections of the non-tumor parenchyma contains kidney cortex and medulla. There are numerous glomeruli seen (over 100). Glomeruli with global sclerosis are not seen. Glomeruli show normal cellularity and reveal no significant pathological changes. On PAS and Jones' silver methenamine stain, the glomerular basement membranes appear of normal thickness. Tubules are well preserved. The interstitium shows no fibrosis or active inflammation. Approximately 10% of the sample shows focal tubular atrophy and interstitial fibrosis, as evidenced on the trichrome stains (AFOG). Arteries and arterioles are unremarkable.

CLINICAL DATA:

History: None given.

Operation: Hand assisted laparoscopic left nephrectomy

Clinical Diagnosis: Left renal mass

TISSUE SUBMITTED: #1. Left kidney

GROSS DESCRIPTION:

The specimen is received fresh, labeled with the patient's name, unit number and "#1. left kidney", and consists of a 545 gram left radical nephrectomy specimen (15.1 x 12.9 x 5.4 cm), to include entire kidney (15.0 x 11.7 x 4.5 cm), portion of dilated ureter (4.3 cm, 0.6 cm in diameter), renal artery (2.5 x 0.5 x 0.5 cm) and renal vein (2.3 x 2.0 cm in diameter). The kidney is partially surfaced by perinephric fat. No adrenal gland is noted. Sectioning demonstrates an encapsulated nodular tan/pink lobulated mass (12.8 x 9.5 x 4.4 cm), which is centrally necrotic and hemorrhagic with an apparent 3.0 x 0.8 x 0.8 cm scar. Mass abuts but does not appear grossly to invade the renal pelvis, which is freely mobile, and occupies the majority of the central portion of the kidney, sparing the poles. The mass expands but does not appear grossly to invade through the renal capsule, which otherwise demonstrates dense hemorrhagic fibrous adhesions. Closest urethral margin is within 3.0 cm (post-fixation), closest renal vein margin is within 2.5 cm (post-fixation), and closest renal artery margin is within 3.0 cm (post-fixation). There are no additional masses noted upon sectioning. Transitional epithelium is tan/white and velvety, cortical medullary junctions are distinct and the uninvolved portions of the cortical surface appears smooth. The perinephric adipose tissue is freely mobile. Three representative sections of the tumor have been submitted for cytogenetics (1A,1B,1C) and to tumor bank (1A,1B,1C). Representative sections of cortex and medulla are

[page 2 of 2]
submitted to tumor bank. Representative non-neoplastic kidney is submitted for electron microscopy, immunofluorescence studies. Representative tumor is retained for electron microscopic studies. Gross photographs are taken. Representative sections corresponding to tissue from 1A, 1B and 1C have been submitted for quick fixation.

Micro 1: margins, shave, mult frags, [REDACTED]
Micro 2: tumor with respect to renal pelvis, adjacent renal tissue, 1 frag, RSS
Micro 3-4: tumor with respect to adjacent renal parenchyma, 2 frags, [REDACTED]
Micro 5-6: tumor and renal capsule (inked blue), 2 frags, [REDACTED]
Micro 7: uninvolved renal parenchyma, 1 frag, [REDACTED]
Micro 8: quick fixed tissue "1A", 1 frag, [REDACTED]
Micro 9: quick fixed tissue "1B", 2 frags, [REDACTED]
Micro 10: quick fixed tissue "1C", 1 frag, [REDACTED]
Micro 11: 2 possible lymph nodes, 2 frags, [REDACTED]
Micro 12: scarred area of tumor, 1 frag, [REDACTED]

SPECIMEN TYPE: KIDNEY PARTIAL OR TOTAL NEPHRECTOMY

Source: NCI Genomic Data Commons file c9bb3175-110c-4664-ab44-41cf907f89c7 (TCGA-KN-8421.9E8F8AFD-E0A0-4AE2-AB6B-30F344E372DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).